Somatic mutation profile of tumor specimen TCGA-EL-A3CX-01A (aliquot TCGA-EL-A3CX-01A-11D-A19J-08) from TCGA case TCGA-EL-A3CX, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 22.8 years (8,344 days).
Specimen TCGA-EL-A3CX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a4bd1a28-a760-404d-a6d5-e2c5e0cc3709.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A3CX-10A (Blood Derived Normal), aliquot TCGA-EL-A3CX-10A-01D-A19M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6db78c60-2138-49a7-8f44-b43b9f69ec66

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 1, Frame Shift Del 1, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 16/17 reads (94%) | hotspot (GDC flag); catalogued as rs587781392, CM920027, COSV57321978; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FHOD3 | c.3547G>A p.A1183T (on ENST00000359247 / NM_001281739.3; = p.A1200T on NM_025135.5) | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.666); catalogued as COSV57171365; called by muse, mutect2, varscan2
- FLNC | c.308C>G p.A103G | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV57954571; called by muse, mutect2, varscan2
- RALGAPA2 | c.3650A>G p.K1217R | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV52495159; called by muse, mutect2
- TMCC1 | c.1202C>G p.A401G (on ENST00000393238 / NM_001349268.2; = p.A77G on NM_015008.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61439847, COSV61442749; called by muse, mutect2, varscan2
- MMRN1 | c.2590_2591del p.D864Hfs*2 | Frame Shift Del (DEL) | VAF 7/20 reads (35%) | called by mutect2, pindel, varscan2
- OR5K4 | c.753T>C p.F251= | Silent (SNP) | VAF 67/129 reads (52%) | catalogued as COSV61583674; called by muse, mutect2, varscan2
- PISD | c.322-1872C>T | Intron (SNP) | VAF 3/48 reads (6%) | catalogued as COSV99837201; called by muse, mutect2
